Gene-level copy-number profile of tumor specimen TCGA-CD-5802-01A from TCGA case TCGA-CD-5802, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 58.4 years (21,331 days).
Specimen TCGA-CD-5802-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.7f9657cb-365f-4dfc-9d32-f084fd5eea3f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CD-5802-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/823e1d36-baa9-438f-b6c9-b08a08a3e2db

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 2: 20,511; copy number 3: 1,118; copy number 4: 34,677; copy number 5: 147; copy number 6: 3,011; copy number 7: 11; copy number 9: 36; copy number 14: 7; copy number 34: 62; copy number 37: 32; copy number 40: 31; copy number 41: 16; copy number 43: 49; copy number 44: 10; copy number 49: 10; copy number 58: 13; copy number 67: 58; copy number 68: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CD-5802-01A-11D-1599-01): tumor purity 0.46, ploidy 1.78, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:113,738,106–114,668,410, 5 genes (within-gene range 0–2): AC093240.1, KCNN2, RN7SKP89, AC010230.1, LINC01957.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 333 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:127,838,486–127,857,804, 1 gene, copy number 9: AC068658.1.
- chr7:16,753,755–16,888,885, 6 genes, copy number 14: TSPAN13, AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2.
- chr7:16,938,225–16,938,557, 1 gene, copy number 14: AC098592.1.
- chr8:127,072,694–127,227,541, 1 gene, copy number 9 (within-gene range 4–9): CASC19.
- chr8:127,253,213–127,742,951, 9 genes, copy number 9: AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC.
- chr8:127,795,962–127,960,695, 4 genes, copy number 9: MIR1204, AC084123.1, TMEM75, MIR1205.
- chr12:23,529,504–24,562,544, 1 gene, copy number 40 (within-gene range 4–40): SOX5.
- chr12:24,212,421–25,648,579, 30 genes, copy number 40: MIR920, SOX5-AS1, LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1.
- chr12:34,190,471–34,249,958, 4 genes, copy number 43 (within-gene range 2–43): AC140847.2, RNA5SP357, DUX4L27, AK6P1.
- chr12:40,196,744–44,503,596, 58 genes, copy number 43–58 (within-gene range 2–58): LRRK2, AC084290.1, MUC19, AC107023.1, RNU6-713P, CNTN1, AC016144.1, AC015540.1, PDZRN4, AC090531.1, RNA5SP360, MTND2P17, MTND1P24, LINC02400, AC090630.1, AC006197.1, AC006197.2, AC023513.1, GXYLT1, YAF2, PPHLN1, AC020629.1, ZCRB1, MIR7851, SNORA74, AC079684.1, RNU6-249P, AC079601.2, Y_RNA, PRICKLE1, AC079601.1, AC079600.3, LINC02402, AC079600.2, AC079600.1, LINC02451, RPS27P21, LINC02450, AC068802.1, AC012038.2, AC012038.1, MRPS36P5, LINC02461, ADAMTS20, AC090525.1, AC090525.2, AC090525.3, EEF1A1P17, PUS7L, AC093012.1, IRAK4, TWF1, TMEM117, ZNF75BP, AC025030.2, AC025030.1, AC025253.1, AC025253.2.
- chr12:55,400,430–56,190,284, 62 genes, copy number 34 (broad region; genes not listed).
- chr12:65,824,460–65,966,291, 1 gene, copy number 44 (within-gene range 2–44): HMGA2.
- chr12:65,934,777–70,920,738, 105 genes, copy number 9–68 (broad region; genes not listed).
- chr12:97,430,884–97,939,121, 18 genes, copy number 9: RMST, MIR1251, AC007351.2, AC007351.3, AC007351.4, AC007351.1, AC018659.4, AC018659.3, AC018659.1, AC018659.7, AC018659.5, AC018659.8, MIR135A2, AC018659.6, AC018659.2, PAFAH1B2P2, RNU6-36P, MIR4495.
- chr19:29,083,094–30,713,538, 32 genes, copy number 37 (within-gene range 4–37): AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
